Somatic mutation profile of tumor specimen MP2PRT-PAULUW-TMP1-A (aliquot MP2PRT-PAULUW-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAULUW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,115 days).
Specimen MP2PRT-PAULUW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2174cc0d-932d-4111-9a58-87f1d8deffdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULUW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULUW-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f1d88a8-60ad-4c27-8cce-a9a513fe91cf

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPAT3 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs367948973; called by muse, mutect2, varscan2
- IDE | c.2866G>A p.V956I | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs375559999; called by muse, mutect2, varscan2
- PAPPA2 | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 201/588 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs758198387, COSV62792453; called by muse, mutect2, varscan2
- DNASE2B | c.804G>A p.W268* | Nonsense Mutation (SNP) | VAF 83/314 reads (26%) | called by muse, mutect2, varscan2
- IGHV4-39 | chr14:106421700 CTCACTGTGTGTCT>TCAGGA | Missense Mutation (DEL) | VAF 93/329 reads (28%) | called by pindel, varscan2*
- KCP | c.3434T>C p.L1145P (on ENST00000620378; = p.L1269P on NM_001366122.1) | Missense Mutation (SNP) | VAF 40/824 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- FTSJ3 | c.2493C>T p.D831= | Silent (SNP) | VAF 169/525 reads (32%) | called by muse, mutect2, varscan2
